Somatic mutation profile of tumor specimen HCM-CSHL-0459-C17-86A (aliquot HCM-CSHL-0459-C17-86A-01D-A85C-36) from HCMI case HCM-CSHL-0459-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen HCM-CSHL-0459-C17-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 305a477d-7523-40f2-a384-f53a5e5d10d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0459-C17-10A (Blood Derived Normal), aliquot HCM-CSHL-0459-C17-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc176a69-d5f2-4c72-9588-1c0c93a1946f

The open-access MAF lists 2,852 somatic variants for this specimen: 2,072 protein-altering or splice-affecting, 691 silent, 89 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,622, Silent 691, Frame Shift Del 228, Nonsense Mutation 79, Frame Shift Ins 77, Intron 47, Splice Region 27, In Frame Del 23, 3'UTR 17, Splice Site 12, 5'Flank 10, 3'Flank 6.

Variants (750 of 2,852; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 158/385 reads (41%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCD1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201568579, CM000643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 177/364 reads (49%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 175/418 reads (42%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA1 | c.668del p.K223Rfs*11 | Frame Shift Del (DEL) | VAF 139/320 reads (43%) | catalogued as rs80357537, CD057384, CS1211735; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5583del p.V1862* | Frame Shift Del (DEL) | VAF 114/266 reads (43%) | catalogued as rs397507790, COSV66450671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 152/362 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 135/298 reads (45%) | catalogued as rs886058579, COSV56974596; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 145/372 reads (39%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LZTR1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 283/571 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587777177, CM140924, COSV99301371; ClinVar: pathogenic; called by muse, varscan2
- MMUT | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 41/534 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs121918251, CM910267, COSV51274211; ClinVar: pathogenic; called by muse, mutect2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 238/455 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 154/351 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1554263326, COSV100640958, COSV61822452, COSV61823434; ClinVar: pathogenic; called by muse, mutect2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 242/243 reads (100%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 228/445 reads (51%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC46A1 | c.194dup p.C66Lfs*99 | Frame Shift Ins (INS) | VAF 223/514 reads (43%) | catalogued as rs80338769; ClinVar: pathogenic; called by mutect2, varscan2
- STK11 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 263/526 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58822445, COSV58825728, COSV58829155; called by mutect2, varscan2
- SYNE1 | c.24284G>A p.R8095H (on ENST00000367255 / NM_182961.4; = p.R8024H on NM_033071.3) | Missense Mutation (SNP) | VAF 187/356 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs119103246, CM075027, COSV54948375; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6327dup p.G2110Wfs*3 (on ENST00000272895 / NM_173076.3; = p.G1792Wfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 190/430 reads (44%) | catalogued as rs1204636023; called by mutect2, pindel, varscan2
- ABCA7 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 250/472 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.513); catalogued as rs756112727; called by muse, mutect2, varscan2
- ABCA9 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 30/326 reads (9%) | catalogued as rs1335682174; called by muse, mutect2
- ABCA9 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 201/396 reads (51%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764821055, COSV60622467; called by muse, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 232/503 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 158/376 reads (42%) | catalogued as rs777439793; called by mutect2, varscan2
- ABCD1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 44/348 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs782492154; called by muse, mutect2, varscan2
- ABCF1 | c.1145G>A p.R382Q (on ENST00000326195 / NM_001025091.2; = p.R344Q on NM_001090.3) | Missense Mutation (SNP) | VAF 214/451 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs749772013; called by muse, mutect2, varscan2
- ABCG1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 223/456 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs564812607; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 188/365 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144857039; called by muse, mutect2, varscan2
- ABHD8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 277/542 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1257742043; called by muse, mutect2, varscan2
- ABL1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 508/785 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs370646520, COSV59325808; called by muse, mutect2, varscan2
- ABLIM3 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 176/550 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV58642691; called by muse, mutect2, varscan2
- ABO | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 499/745 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs377147187; called by muse, mutect2, varscan2
- ABRA | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 183/368 reads (50%) | catalogued as rs765786301; called by muse, mutect2, varscan2
- AC013489.1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 238/472 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs780142606; called by muse, mutect2, varscan2
- ACACA | c.2207G>A p.G736D | Missense Mutation (SNP) | VAF 24/656 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs747456606; called by muse, mutect2
- ACACB | c.7097C>T p.T2366M | Missense Mutation (SNP) | VAF 197/426 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs754980151, COSV58131584; called by muse, mutect2, varscan2
- ACADS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 230/471 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54370327; called by muse, mutect2, varscan2
- ACAP3 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 294/576 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1319532754; called by muse, varscan2
- ACIN1 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 288/594 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs746023844, COSV99399692; called by muse, varscan2
- ACO1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 180/412 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328936319, COSV104401460; called by muse, mutect2, varscan2
- ACOT7 | c.811G>A p.V271I (on ENST00000377855 / NM_181864.3; = p.V261I on NM_007274.4) | Missense Mutation (SNP) | VAF 173/387 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs781767639; called by muse, mutect2, varscan2
- ACOX3 | c.876C>T p.D292= | Splice Region (SNP) | VAF 161/313 reads (51%) | catalogued as rs751029086; called by muse, mutect2, varscan2
- ACP7 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 275/558 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs546523874, COSV58700546; called by muse, varscan2
- ACSF3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 259/584 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs144411003; called by muse, mutect2
- ACSM3 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55503011; called by muse, varscan2
- ACSS1 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 268/570 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241493290; called by muse, mutect2, varscan2
- ACTC1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 136/280 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1437269590, COSV51757644, COSV99291859; called by muse, mutect2, varscan2
- ACTN2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1057523721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 176/351 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs201452185; ClinVar: benign; called by muse, mutect2, varscan2
- ADAD1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 199/400 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314917408; called by muse, mutect2, varscan2
- ADAMTS10 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 278/615 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as rs782813134, COSV54353240; called by muse, mutect2, varscan2
- ADAMTS4 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 222/490 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs767813779; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 415/1247 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1233835454, COSV63203957; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 534/841 reads (63%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as rs886063646, COSV63204764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 246/516 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs201047866; called by muse, mutect2, varscan2
- ADARB1 | c.1601G>A p.R534H (on ENST00000360697 / NM_001346687.2; = p.R494H on NM_001112.4) | Missense Mutation (SNP) | VAF 218/485 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201477864; called by muse, mutect2, varscan2
- ADCY2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 272/549 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767957240; called by muse, mutect2, varscan2
- ADCY2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100603438; called by muse, mutect2, varscan2
- ADGRD1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 216/399 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1221659296; called by muse, mutect2, varscan2
- ADGRL3 | c.3091del p.V1031Cfs*39 (on ENST00000506720 / NM_001322402.2; = p.V963Cfs*39 on NM_015236.6) | Frame Shift Del (DEL) | VAF 239/535 reads (45%) | catalogued as COSV104438836; called by mutect2, pindel, varscan2
- ADGRL3 | c.4534G>A p.E1512K (on ENST00000506720 / NM_001322402.2; = p.E1401K on NM_015236.6) | Missense Mutation (SNP) | VAF 221/471 reads (47%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.228); catalogued as rs751513777, COSV72231753; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2, varscan2
- ADPRS | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 161/365 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1293906648, COSV52882351; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 172/410 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- AFF4 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 387/630 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as rs1312528517; called by muse, mutect2, varscan2
- AGO1 | c.49dup p.L17Pfs*28 | Frame Shift Ins (INS) | VAF 168/360 reads (47%) | catalogued as rs752471592; called by mutect2, varscan2
- AGO4 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 116/231 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs750167672; called by muse, mutect2, varscan2
- AGRN | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 323/699 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV101038734; called by muse, mutect2, varscan2
- AGRN | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 367/759 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs757377436; called by muse, mutect2, varscan2
- AHDC1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 315/593 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201616346; called by muse, varscan2
- AIFM3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 240/518 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553803201; called by muse, mutect2
- AIPL1 | c.784+4C>T | Splice Region (SNP) | VAF 228/408 reads (56%) | catalogued as rs375600133; called by muse, mutect2, varscan2
- AKAP17A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 425/426 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs775070085, COSV58312051; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 142/322 reads (44%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.6073C>T p.Q2025* (on ENST00000359028; = p.Q1993* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/169 reads (56%) | catalogued as rs786205714, COSV62345120; called by muse, mutect2, varscan2
- ALAS2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs772482624, CM1312006, COSV58190490; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH2 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 275/548 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751980357, COSV55669488; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 260/538 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALDH3B2 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 36/577 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs757916431, COSV62427603; called by muse, mutect2
- ALG10B | c.980del p.L327Wfs*5 | Frame Shift Del (DEL) | VAF 177/450 reads (39%) | catalogued as COSV58145139; called by mutect2, pindel, varscan2
- ALOX5 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 321/653 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1312171446; called by muse, mutect2, varscan2
- ALPK2 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 224/438 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs147290810; called by muse, mutect2, varscan2
- ALPP | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 210/560 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs755793283, COSV101235192; called by muse, mutect2, varscan2
- AMOT | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 313/357 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs180687453, COSV59062221; called by muse, mutect2, varscan2
- AMOTL1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 179/393 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs755948371, COSV100504867; called by muse, mutect2, varscan2
- ANGPTL1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as rs367579998; called by muse, mutect2, varscan2
- ANGPTL7 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 197/416 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs779740660; called by muse, mutect2, varscan2
- ANGPTL8 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 183/376 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs781506138; called by muse, mutect2, varscan2
- ANK1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 153/319 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55871816; called by muse, mutect2, varscan2
- ANK2 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 136/289 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138381417; called by muse, mutect2, varscan2
- ANK3 | c.6778G>A p.G2260S | Missense Mutation (SNP) | VAF 147/332 reads (44%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs192587828, COSV99778504; called by muse, mutect2, varscan2
- ANKH | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 167/371 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764910926; called by muse, mutect2, varscan2
- ANKLE1 | c.1465C>T p.Q489* (on ENST00000394458; = p.Q435* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 201/427 reads (47%) | catalogued as rs560635345; called by muse, mutect2, varscan2
- ANKRD11 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 345/705 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56369004; called by muse, mutect2, varscan2
- ANKRD27 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 224/477 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs759978285; called by muse, varscan2
- ANKRD31 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1399754846; called by muse, varscan2
- ANKRD34A | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 24/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100041238; called by muse, mutect2
- ANKRD36B | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs369666439; called by muse, mutect2, varscan2
- ANKRD44 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 85/210 reads (40%) | catalogued as rs147529433; called by muse, varscan2
- ANP32B | c.579_581del p.E193del | In Frame Del (DEL) | VAF 296/496 reads (60%) | catalogued as rs548651278; called by pindel, varscan2
- ANTKMT | c.686dup p.L230Pfs*? | Frame Shift Ins (INS) | VAF 194/533 reads (36%) | catalogued as rs755358433; called by mutect2, pindel, varscan2
- AOX1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 104/196 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV65984378; called by mutect2, varscan2
- AP000812.4 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 234/501 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs1372399805, COSV99597694; called by muse, mutect2, varscan2
- AP3D1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 205/458 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372956453; called by muse, mutect2, varscan2
- AQP3 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 260/564 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs756008789; called by muse, mutect2, varscan2
- AQP7 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 242/500 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs780270047, COSV53035946; called by muse, mutect2, varscan2
- ARAF | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763351013, COSV51694303; called by muse, mutect2, varscan2
- ARAP1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 233/526 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs768446677; called by muse, mutect2, varscan2
- ARFGAP3 | c.669del p.G224Afs*32 | Frame Shift Del (DEL) | VAF 83/222 reads (37%) | catalogued as rs1436718702, COSV54312627; called by mutect2, pindel, varscan2
- ARFGEF3 | c.5599G>A p.A1867T | Missense Mutation (SNP) | VAF 271/512 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs766044916, COSV52457823; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARHGAP21 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 243/497 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs771305026, COSV100256084; called by muse, varscan2
- ARHGAP25 | c.1846C>T p.R616C (on ENST00000409202 / NM_001007231.3; = p.R608C on NM_014882.3) | Missense Mutation (SNP) | VAF 266/567 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs764265797, COSV54903451; called by muse, mutect2, varscan2
- ARHGAP39 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 348/689 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777563207; called by muse, mutect2, varscan2
- ARHGAP44 | c.198C>T p.S66= | Splice Region (SNP) | VAF 112/261 reads (43%) | catalogued as rs202018989; called by muse, mutect2, varscan2
- ARHGAP45 | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 178/390 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100491023; called by muse, mutect2, varscan2
- ARHGEF11 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 164/332 reads (49%) | catalogued as COSV63811869; called by muse, mutect2, varscan2
- ARHGEF17 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as rs567330760; called by muse, mutect2, varscan2
- ARHGEF18 | c.2860G>A p.E954K (on ENST00000359920 / NM_001130955.2; = p.E850K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 378/709 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs993334421, COSV100150146; called by muse, mutect2, varscan2
- ARL10 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 269/752 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV53798213; called by muse, mutect2, varscan2
- ARL6 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 138/317 reads (44%) | catalogued as COSV100256607; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 177/414 reads (43%) | catalogued as COSV62230627; called by mutect2, pindel, varscan2
- ASAH2 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 182/379 reads (48%) | catalogued as rs1194660932, COSV61483494; called by muse, mutect2, varscan2
- ASS1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 367/602 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs201445618; called by muse, mutect2, varscan2
- ASTN1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 155/304 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1364819044; called by muse, mutect2, varscan2
- ASTN2 | c.3989G>A p.R1330Q (on ENST00000313400 / NM_001365069.1; = p.R1279Q on NM_014010.5) | Missense Mutation (SNP) | VAF 161/524 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.978); catalogued as rs367824366; called by muse, mutect2, varscan2
- ATG2B | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 212/478 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746956149; called by muse, mutect2, varscan2
- ATG9B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 156/321 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1312209539, COSV99871688; called by muse, mutect2, varscan2
- ATG9B | c.2646C>T p.D882= | Splice Region (SNP) | VAF 141/337 reads (42%) | catalogued as rs545593603, COSV99872428; called by muse, varscan2
- ATP5MC2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 221/463 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs781062050, COSV58601745; called by muse, mutect2, varscan2
- ATP8B1 | c.3695C>T p.S1232L | Missense Mutation (SNP) | VAF 318/638 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs778749552, COSV52173063; called by muse, varscan2
- ATRIP | c.2258C>T p.P753L (on ENST00000320211 / NM_130384.3; = p.P726L on NM_032166.4) | Missense Mutation (SNP) | VAF 62/442 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs369842101; called by muse, mutect2, varscan2
- ATXN3L | c.585del p.K195Nfs*2 | Frame Shift Del (DEL) | VAF 226/324 reads (70%) | catalogued as rs1411781059; called by mutect2, pindel, varscan2
- AVPI1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 325/698 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773089599; called by muse, mutect2, varscan2
- AXIN1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 268/607 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145608130; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 357/707 reads (50%) | catalogued as rs778012871; called by mutect2, varscan2
- B3GLCT | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 226/491 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769182025; called by muse, mutect2, varscan2
- B3GNT9 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 329/655 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329819842, COSV54628915; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 78/174 reads (45%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAG5 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 189/368 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758744586, COSV99915014; called by muse, mutect2, varscan2
- BEND7 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 193/414 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1184445078; called by muse, varscan2
- BEST2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 213/423 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs757587843, COSV50363408; called by muse, mutect2, varscan2
- BHLHA15 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 400/826 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs750704418; called by muse, mutect2, varscan2
- BICD1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 203/461 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99863162; called by muse, mutect2, varscan2
- BICRA | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 456/880 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1215558782, COSV67604756; called by muse, mutect2, varscan2
- BIRC6 | c.9685C>T p.L3229F | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1216100664; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2734G>A p.V912I | Missense Mutation (SNP) | VAF 227/499 reads (45%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.023); catalogued as rs140135562; called by muse, mutect2, varscan2
- BLNK | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 129/291 reads (44%) | catalogued as rs200501515; called by muse, mutect2, varscan2
- BMERB1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 222/424 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208487544, COSV100252561; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 196/500 reads (39%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC1 | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 239/501 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61757595; called by muse, mutect2, varscan2
- BRAP | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 232/504 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRAT1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 222/487 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs745563920, COSV61397659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 263/501 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1254272998, COSV99350570; called by muse, mutect2, varscan2
- BRD3 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 320/541 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs774040378, COSV57702822; called by muse, mutect2, varscan2
- BRPF3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 320/628 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1442029620; called by muse, mutect2, varscan2
- BRSK1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 316/675 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs755357977; called by muse, mutect2, varscan2
- BRSK1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 249/552 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200690719; called by muse, mutect2, varscan2
- BSCL2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 156/331 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs202072835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 282/600 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771863939; called by muse, mutect2, varscan2
- BTNL9 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 244/659 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs781133085; called by muse, mutect2, varscan2
- C11orf95 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 435/774 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1192269990, COSV58032727; called by muse, varscan2
- C18orf54 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 116/232 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as rs146934571, COSV100266395; called by muse, varscan2
- C2CD5 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs139822705; called by muse, mutect2, varscan2
- C5 | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 304/503 reads (60%) | catalogued as COSV56325970; called by muse, mutect2, varscan2
- C5orf46 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 321/477 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs375956579; called by muse, mutect2, varscan2
- C6orf132 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 420/757 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1275712359; called by muse, mutect2, varscan2
- C6orf132 | c.920del p.P307Qfs*210 | Frame Shift Del (DEL) | VAF 285/717 reads (40%) | catalogued as COSV59375430; called by mutect2, pindel, varscan2
- CACNA1A | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 123/287 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs1353041373; called by muse, mutect2, varscan2
- CACNA1B | c.4703G>A p.R1568H | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99501175; called by muse, mutect2, varscan2
- CACNA1I | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 220/409 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1278074840, COSV60802941; called by muse, mutect2, varscan2
- CACNA1S | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 211/441 reads (48%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.992); catalogued as rs373701906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 199/385 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781210506, COSV99818083; called by muse, mutect2, varscan2
- CALD1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 222/428 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646346; called by muse, mutect2, varscan2
- CALHM3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 372/746 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs867022038; called by muse, mutect2, varscan2
- CAMKK2 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 267/586 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1310112012; called by muse, varscan2
- CAMTA1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 289/613 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1470142432, COSV57909520; called by muse, mutect2, varscan2
- CAMTA1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 190/394 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1181886794; called by muse, mutect2, varscan2
- CAPN10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 196/424 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as rs770374333; called by muse, mutect2, varscan2
- CAPN10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 297/654 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.059); catalogued as rs752063033; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 143/401 reads (36%) | catalogued as rs762770988, COSV62756627; called by pindel, varscan2
- CARD6 | c.2681C>A p.P894H | Missense Mutation (SNP) | VAF 260/508 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99620956; called by mutect2, varscan2
- CASKIN2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 194/432 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs371781299; called by muse, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 173/372 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 275/593 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs530151570, COSV59740183; called by muse, mutect2, varscan2
- CASZ1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 244/525 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs146887532; called by muse, mutect2, varscan2
- CCDC102B | c.1259dup p.N420Kfs*13 | Frame Shift Ins (INS) | VAF 82/184 reads (45%) | catalogued as rs562973346; called by mutect2, varscan2
- CCDC105 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 327/682 reads (48%) | catalogued as rs372493151; called by muse, mutect2, varscan2
- CCDC110 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 133/368 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs546423737, COSV56873334; called by muse, mutect2
- CCDC113 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 161/338 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147141699; called by muse, mutect2, varscan2
- CCDC120 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 452/453 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782072841, COSV64480869; called by muse, mutect2, varscan2
- CCDC136 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 203/463 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1038089391; called by muse, mutect2, varscan2
- CCDC15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760911695, COSV100776989, COSV61084753; called by muse, varscan2
- CCDC166 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 463/970 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV101545877; called by muse, mutect2, varscan2
- CCDC170 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 160/332 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs200841666, COSV53339624; called by muse, mutect2
- CCDC180 | c.2196G>T p.E732D | Missense Mutation (SNP) | VAF 226/684 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as rs12353275; called by mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 149/487 reads (31%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC181 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 223/450 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs187334513; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 120/278 reads (43%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 56/136 reads (41%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC81 | c.1400C>T p.A467V (on ENST00000445632 / NM_001156474.2; = p.A377V on NM_021827.4) | Missense Mutation (SNP) | VAF 152/327 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs771099705; called by muse, mutect2, varscan2
- CCER2 | c.660_662dup p.H220dup | In Frame Ins (INS) | VAF 326/756 reads (43%) | catalogued as rs144792695; called by mutect2, varscan2
- CCHCR1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 369/741 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1165145831; called by muse, mutect2, varscan2
- CCHCR1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 299/642 reads (47%) | catalogued as rs767157475, COSV100885732; called by muse, mutect2, varscan2
- CCNJL | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 262/755 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs748396775; called by muse, mutect2, varscan2
- CCR6 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs774906837; called by muse, mutect2, varscan2
- CCR9 | c.430A>G p.R144G (on ENST00000357632 / NM_031200.3; = p.R132G on NM_006641.4) | Missense Mutation (SNP) | VAF 221/471 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748863151; called by muse, mutect2, varscan2
- CD151 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 177/362 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs1019424026; called by muse, mutect2, varscan2
- CD247 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 195/459 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs144963570; called by muse, mutect2, varscan2
- CD40 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 191/368 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754006524, COSV100953780; called by muse, mutect2, varscan2
- CD5L | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 218/462 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs74121552, COSV63823026; called by muse, mutect2, varscan2
- CDC123 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 151/346 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752328200, COSV55395725; called by muse, mutect2, varscan2
- CDC16 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 152/323 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52958720; called by muse, mutect2, varscan2
- CDC42BPB | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 257/514 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780626139; called by muse, mutect2, varscan2
- CDH10 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 272/545 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760804087, COSV52572298, COSV52585105; called by muse, mutect2, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 91/255 reads (36%) | catalogued as rs1568168060; called by mutect2, pindel, varscan2
- CDH2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 126/286 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1228174771; called by muse, mutect2, varscan2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 232/478 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, varscan2
- CDHR2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 296/913 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs745929407; called by muse, mutect2
- CDK12 | c.4067G>A p.R1356Q (on ENST00000447079 / NM_016507.4; = p.R1347Q on NM_015083.3) | Missense Mutation (SNP) | VAF 268/551 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.273); catalogued as rs761089485, COSV71001791; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4223G>A p.R1408H | Missense Mutation (SNP) | VAF 219/372 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1014026370; called by muse, mutect2, varscan2
- CDK6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373488172, COSV56008836; called by muse, mutect2, varscan2
- CDKN3 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 165/326 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286825216; called by muse, mutect2, varscan2
- CDRT1 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 170/358 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs369935359; called by muse, mutect2, varscan2
- CDT1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 61/666 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs202071237, COSV56348835; called by muse, mutect2
- CEACAM16 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 325/661 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777496967, COSV101312772; called by muse, mutect2, varscan2
- CELF2 | c.1127C>T p.T376M (on ENST00000416382 / NM_001025077.3; = p.T389M on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 238/493 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100258199; called by muse, mutect2, varscan2
- CELSR2 | c.5410G>A p.A1804T | Missense Mutation (SNP) | VAF 273/565 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs770840359; called by muse, mutect2, varscan2
- CEMIP2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 169/397 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs778331613, COSV100987406; called by muse, mutect2, varscan2
- CENPF | c.8509G>A p.D2837N | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs138734779; called by muse, mutect2, varscan2
- CENPQ | c.125del p.N42Ifs*5 | Frame Shift Del (DEL) | VAF 72/155 reads (46%) | catalogued as rs756590976; called by mutect2, varscan2
- CEP131 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 225/517 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs143028785; called by muse, mutect2, varscan2
- CEP170B | c.723del p.E242Rfs*41 (on ENST00000453495; = p.E171Rfs*41 on NM_015005.3) | Frame Shift Del (DEL) | VAF 397/966 reads (41%) | catalogued as COSV69024902; called by mutect2, pindel, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 108/312 reads (35%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CEP192 | c.6476_6477del p.S2159Cfs*7 | Frame Shift Del (DEL) | VAF 154/431 reads (36%) | catalogued as rs1433048204; called by pindel, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 202/386 reads (52%) | catalogued as rs759430139; called by mutect2, varscan2
- CEP95 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782398984; called by muse, mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 191/395 reads (48%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP46 | c.7358C>T p.A2453V | Missense Mutation (SNP) | VAF 200/454 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs768215654; called by muse, mutect2, varscan2
- CFAP61 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 214/434 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs567725378; called by muse, varscan2
- CGB1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1331501646; called by muse, mutect2, varscan2
- CGB2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1429495580; called by muse, mutect2, varscan2
- CGB3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 150/601 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1462326318; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 105/330 reads (32%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD2 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 263/630 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1060503522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100560575; called by muse, mutect2, varscan2
- CHD4 | c.3244C>T p.R1082C (on ENST00000357008 / NM_001363606.2; = p.R1095C on NM_001273.5) | Missense Mutation (SNP) | VAF 206/481 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100538432; called by muse, mutect2, varscan2
- CHD7 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 233/492 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as rs765180149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.6080G>T p.R2027L | Missense Mutation (SNP) | VAF 131/268 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV71112607; called by mutect2, varscan2
- CHFR | c.833G>A p.R278H (on ENST00000432561 / NM_001161345.1; = p.R237H on NM_018223.2) | Missense Mutation (SNP) | VAF 211/457 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs375174098; called by muse, mutect2, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 249/565 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, mutect2, varscan2
- CHID1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 285/578 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs777138598; called by muse, mutect2, varscan2
- CHRNA7 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401153406, COSV100181202; called by mutect2, varscan2
- CHRNB2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 261/562 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs796052326, COSV100872517; ClinVar: uncertain significance; called by muse, varscan2
- CHST1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 375/796 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57322988; called by muse, mutect2, varscan2
- CHST8 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 328/700 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759507836; called by muse, mutect2, varscan2
- CIAO1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs772533972; called by muse, mutect2, varscan2
- CIC | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 304/705 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50547229; called by muse, mutect2, varscan2
- CIP2A | c.2422del p.T808Qfs*29 | Frame Shift Del (DEL) | VAF 77/205 reads (38%) | catalogued as COSV99843074; called by mutect2, pindel, varscan2
- CISD2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs868634687; called by muse, mutect2, varscan2
- CKM | c.1096_1098del p.K366del | In Frame Del (DEL) | VAF 184/412 reads (45%) | catalogued as rs780083622; called by pindel, varscan2
- CLASP1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1472982745, COSV55336545; called by muse, mutect2, varscan2
- CLASRP | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 202/460 reads (44%) | SIFT tolerated (0.08); catalogued as rs780663630; called by muse, mutect2
- CLCN7 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 166/373 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1400598641, COSV99246906; called by muse, mutect2, varscan2
- CLIP2 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 287/596 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.179); catalogued as rs782545372, COSV56281635; called by muse, mutect2, varscan2
- CLIP3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 183/398 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV62112754; called by muse, mutect2, varscan2
- CLK3 | c.712C>T p.R238C (on ENST00000395066 / NM_001130028.1; = p.R90C on NM_003992.4) | Missense Mutation (SNP) | VAF 286/603 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs767369515; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 102/241 reads (42%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1L | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 212/504 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1019362368; called by muse, mutect2, varscan2
- CLSTN1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 161/370 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363487449; called by muse, mutect2, varscan2
- CMTR1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 122/271 reads (45%) | catalogued as rs747046392; called by muse, mutect2, varscan2
- CMTR1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 183/413 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs759199278; called by muse, mutect2, varscan2
- CNBD1 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 134/254 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73074582; called by muse, mutect2, varscan2
- CNOT6L | c.538C>T p.R180* (on ENST00000504123 / NM_001286790.2; = p.R175* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 163/369 reads (44%) | catalogued as COSV53701253; called by muse, mutect2, varscan2
- CNR1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV62986486; called by muse, mutect2, varscan2
- COL11A2 | c.4482G>A p.P1494= (on ENST00000341947 / NM_080680.3; = p.P1387= on NM_080679.2) | Splice Region (SNP) | VAF 301/625 reads (48%) | catalogued as rs142586242, COSV59503302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 169/417 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128683, COSV65422174; called by muse, mutect2, varscan2
- COL5A1 | c.4121C>T p.T1374M | Missense Mutation (SNP) | VAF 348/546 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs151115748; ClinVar: uncertain significance; called by muse, varscan2
- COL5A1 | c.4909C>T p.R1637C | Missense Mutation (SNP) | VAF 282/774 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753433375, COSV100880383, COSV65669482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 213/458 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs375452881; called by muse, mutect2, varscan2
- COL6A6 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 160/358 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.353); catalogued as rs764994836, COSV62023950; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 205/496 reads (41%) | catalogued as rs941174282; called by mutect2, pindel, varscan2
- COPA | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 202/403 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253097566, COSV54107149; called by muse, mutect2, varscan2
- COPG1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 185/398 reads (46%) | catalogued as rs775727605, COSV59116628; called by muse, mutect2, varscan2
- COPRS | c.90del p.S31Afs*25 | Frame Shift Del (DEL) | VAF 220/556 reads (40%) | catalogued as rs1567771049; called by mutect2, pindel, varscan2
- CORIN | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 222/471 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV99904277; called by muse, mutect2
- CPNE4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 29/572 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1355312776, COSV101456545; called by muse, mutect2
- CPNE5 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 222/465 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs778477100; called by muse, mutect2, varscan2
- CPNE8 | c.285del p.F95Lfs*41 | Frame Shift Del (DEL) | VAF 51/151 reads (34%) | catalogued as COSV58849117; called by mutect2, pindel, varscan2
- CPT1A | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139057953; called by muse, mutect2, varscan2
- CR2 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 150/366 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as rs1367099391; called by muse, mutect2, varscan2
- CRAT | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 172/506 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760770816, COSV100540034; called by muse, mutect2, varscan2
- CRB1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 225/469 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as CM040711, COSV66329127, COSV66331096; called by muse, mutect2, varscan2
- CRTC2 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 257/540 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1433609577; called by muse, mutect2, varscan2
- CSF1R | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 227/709 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs372068592; called by muse, mutect2, varscan2
- CSF3R | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 201/406 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779227407, COSV58966490; called by muse, mutect2, varscan2
- CSMD2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 184/388 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759408814; called by muse, mutect2, varscan2
- CSMD2 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 165/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53882610; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 149/381 reads (39%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1E | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 291/580 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as rs759550035; called by muse, varscan2
- CSPG4 | c.6739C>T p.R2247* | Nonsense Mutation (SNP) | VAF 233/486 reads (48%) | catalogued as rs777249049, COSV57889753; called by muse, mutect2, varscan2
- CST6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 237/488 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1411186911; called by muse, mutect2, varscan2
- CTNNA2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 282/516 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs752704214, COSV63547968; called by muse, mutect2, varscan2
- CTNNAL1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 287/450 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1250786842; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 228/558 reads (41%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNNBL1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 183/399 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757144734; called by muse, mutect2, varscan2
- CTNND1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 194/400 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as rs754613241, COSV62382631; called by muse, mutect2, varscan2
- CTSV | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 469/722 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372363372; called by muse, mutect2, varscan2
- CTTN | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 184/368 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs267603163; called by muse, varscan2
- CWC22 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 200/461 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs373594028; called by muse, mutect2, varscan2
- CWC27 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 164/329 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765721927; called by muse, mutect2, varscan2
- CYB5R1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 188/421 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs755233575, COSV100924852; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 232/234 reads (99%) | catalogued as rs745836350; called by mutect2, varscan2
- CYFIP1 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 185/400 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs769699388; called by muse, mutect2, varscan2
- CYHR1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 175/373 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV71324651; called by muse, mutect2, varscan2
- CYP1B1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 414/789 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as CM066030; called by muse, mutect2, varscan2
- CYP46A1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 286/624 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.978); catalogued as rs756141971; called by muse, mutect2, varscan2
- CYTH2 | c.960G>A p.P320= (on ENST00000427476; = p.P319= on NM_004228.7) | Splice Region (SNP) | VAF 160/356 reads (45%) | catalogued as rs766860687, COSV57309254; called by muse, varscan2
- DACT3 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 122/740 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.565); catalogued as COSV56258935; called by muse, mutect2, varscan2
- DAPK1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 177/367 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs370724837; called by muse, mutect2, varscan2
- DAZAP1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as rs1053723670, COSV99245627; called by muse, mutect2, varscan2
- DBF4B | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 264/549 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774163525; called by muse, mutect2, varscan2
- DCAF1 | c.3008C>T p.T1003M | Missense Mutation (SNP) | VAF 271/528 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs782486639; called by muse, varscan2
- DCAF12L2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 307/308 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63583920; called by muse, mutect2, varscan2
- DCAF5 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 256/512 reads (50%) | catalogued as COSV58458695; called by muse, mutect2, varscan2
- DCHS1 | c.7756G>A p.V2586M | Missense Mutation (SNP) | VAF 219/442 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs747141130, COSV54996502; called by muse, mutect2, varscan2
- DCHS1 | c.5431C>T p.R1811W | Missense Mutation (SNP) | VAF 213/465 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757316767, COSV55044575; called by muse, mutect2, varscan2
- DCXR | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 194/363 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752090622; called by muse, varscan2
- DDIT4L | c.257A>G p.Q86R | Missense Mutation (SNP) | VAF 47/386 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778379429; called by muse, mutect2, varscan2
- DDN | c.1411dup p.R471Pfs*31 | Frame Shift Ins (INS) | VAF 291/744 reads (39%) | catalogued as rs773412144; called by mutect2, pindel, varscan2
- DDRGK1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 198/392 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753666292, COSV100621543; called by muse, varscan2
- DDX11 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 131/304 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs751955009, COSV99299994; called by muse, mutect2, varscan2
- DDX56 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 24/658 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51836916; called by muse, mutect2
- DENND1A | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 596/928 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs754417395; called by muse, mutect2, varscan2
- DENND4A | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 240/485 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248901572; called by muse, mutect2, varscan2
- DESI2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 189/417 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.236); catalogued as rs373776959; called by muse, mutect2, varscan2
- DGKD | c.2027G>T p.S676I (on ENST00000264057 / NM_152879.3; = p.S632I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776171645, COSV51039375; called by muse, mutect2, varscan2
- DGKZ | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 96/884 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.381); catalogued as rs1194150493; called by muse, mutect2
- DHX16 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 346/630 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1273530977, COSV64579712; called by muse, mutect2, varscan2
- DHX57 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs772689230, COSV54892254; called by muse, mutect2, varscan2
- DHX9 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 174/411 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV62359156; called by muse, mutect2, varscan2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2, varscan2
- DIP2C | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 276/559 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1485067164; called by muse, mutect2, varscan2
- DISP3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 75/606 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1319873156, COSV53825140, COSV99609035; called by muse, mutect2, varscan2
- DLEC1 | c.4387G>A p.V1463M | Missense Mutation (SNP) | VAF 135/277 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199537711; called by muse, mutect2, varscan2
- DLG1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 92/251 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs560145346; called by muse, mutect2, varscan2
- DLGAP5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 154/379 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766110350; called by muse, mutect2, varscan2
- DMAC2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 219/481 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148395303; called by muse, mutect2, varscan2
- DMBX1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 261/534 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100760721; called by muse, mutect2, varscan2
- DNAH12 | c.6362G>A p.R2121H (on ENST00000351747; = p.R2140H on NM_001366028.2) | Missense Mutation (SNP) | VAF 188/432 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969549110, COSV61054794; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 237/477 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DNAH3 | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 151/297 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765153588; called by muse, mutect2, varscan2
- DNAH5 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 156/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774191944, COSV54217609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 156/337 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777085250; called by muse, mutect2, varscan2
- DNHD1 | c.6187G>A p.G2063S | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757027777; called by muse, varscan2
- DNMT3A | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 220/467 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as rs1183198167, COSV53038083, COSV53044768; called by muse, mutect2, varscan2
- DOCK4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202096330; called by muse, mutect2, varscan2
- DOHH | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 420/875 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs778229924, COSV51744035; called by muse, mutect2, varscan2
- DPH7 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 280/551 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs922412367; called by muse, mutect2, varscan2
- DPP9 | c.2531G>A p.C844Y (on ENST00000598800; = p.C873Y on NM_139159.5) | Missense Mutation (SNP) | VAF 210/482 reads (44%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.484); catalogued as rs981667065; called by muse, mutect2, varscan2
- DPYSL2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765160936, COSV60782528; called by muse, mutect2
- DRC1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 334/754 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.919); catalogued as rs149082901; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 240/493 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- DSCAML1 | c.3473G>A p.R1158Q (on ENST00000321322; = p.R1098Q on NM_020693.4) | Missense Mutation (SNP) | VAF 246/460 reads (53%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.726); catalogued as rs953338496; called by muse, varscan2
- DSCAML1 | c.2627G>A p.R876Q (on ENST00000321322; = p.R816Q on NM_020693.4) | Missense Mutation (SNP) | VAF 280/604 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as rs1028890107, COSV58382762; called by muse, mutect2, varscan2
- DST | c.3280C>A p.L1094M (on ENST00000361203 / NM_001374722.1; = p.L768M on NM_001723.6) | Missense Mutation (SNP) | VAF 187/414 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs756379041, COSV55031525; called by muse, mutect2, varscan2
- DTNA | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 132/293 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774480677, COSV99313992; called by muse, mutect2, varscan2
- DTNB | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs768951661, COSV56480745; called by muse, mutect2, varscan2
- DUSP8 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 372/758 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as rs762548136; called by muse, mutect2, varscan2
- DVL1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 279/585 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as rs1254209708, COSV66678109; called by muse, mutect2
- DYNC1H1 | c.10631G>A p.R3544H | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761216533, COSV64137354; called by muse, mutect2, varscan2
- DYNC1H1 | c.11389G>A p.V3797M | Missense Mutation (SNP) | VAF 273/584 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760876077, COSV100795447; called by muse, mutect2, varscan2
- DYTN | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 226/442 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV71752718; called by muse, mutect2, varscan2
- ECE1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1295873616; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1325_1327del p.K442del | In Frame Del (DEL) | VAF 126/315 reads (40%) | catalogued as rs758872276; called by pindel, varscan2
- EEF2K | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 254/548 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53784849; called by muse, mutect2, varscan2
- EFCAB9 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 149/456 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1356894091; called by muse, mutect2, varscan2
- EFEMP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 346/686 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779247685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 199/462 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as rs757316290, COSV53065375; called by muse, mutect2, varscan2
- ELANE | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 241/451 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.218); catalogued as rs1396230082, CM104210, COSV52256451; called by muse, mutect2, varscan2
- ELMOD2 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 203/417 reads (49%) | catalogued as rs750143144; called by muse, mutect2, varscan2
- ELOA | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 178/395 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs775582884; called by muse, mutect2, varscan2
- EMC1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748974716, COSV61887025; called by muse, mutect2, varscan2
- EMILIN1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 251/522 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs201575918, COSV66695118; called by muse, mutect2, varscan2
- ENOX1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs764001017, COSV54894322; called by muse, mutect2, varscan2
- EPHA8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 238/523 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756576145, COSV51296296; called by muse, mutect2, varscan2
- EPHB2 | c.2191G>A p.A731T (on ENST00000400191 / NM_001309193.2; = p.A732T on NM_004442.7) | Missense Mutation (SNP) | VAF 222/474 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs142161660; called by muse, varscan2
- EPHB2 | c.3120del p.F1040Lfs*43 | Frame Shift Del (DEL) | VAF 190/433 reads (44%) | catalogued as rs770822649; called by mutect2, pindel, varscan2
- EPHX1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 271/580 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs763600235; called by muse, varscan2
- EPM2AIP1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 307/612 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV51621142; called by muse, mutect2, varscan2
- EPN1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 251/520 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs774551624; called by muse, mutect2, varscan2
- EPN2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs951398293, COSV59061029; called by muse, mutect2, varscan2
- ERN1 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 276/589 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs200358341; called by muse, mutect2, varscan2
- ERN1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 162/340 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs780870849, COSV70500856; called by muse, mutect2, varscan2
- ERN1 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 157/307 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs370673725; called by muse, mutect2, varscan2
- ESPNL | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 246/520 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs759308208, COSV54540000; called by muse, mutect2, varscan2
- ESRP1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 147/357 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64410745; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 196/388 reads (51%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 175/434 reads (40%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EVX2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 340/696 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs760847501; called by muse, varscan2
- EXO5 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 212/435 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs781656662; called by muse, mutect2, varscan2
- EXTL3 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 228/453 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as rs139633425, COSV55038590; called by muse, varscan2
- EYS | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 188/396 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs760342117; called by muse, mutect2, varscan2
- FAM133B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as rs772730489; called by muse, mutect2, varscan2
- FAM13B | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 208/320 reads (65%) | catalogued as rs756297490, COSV50365444; called by muse, mutect2, varscan2
- FAM166A | c.558dup p.A187Rfs*23 | Frame Shift Ins (INS) | VAF 94/241 reads (39%) | catalogued as rs766839703; called by mutect2, pindel
- FAM168A | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 207/474 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs568533341; called by muse, mutect2, varscan2
- FAM170B | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 250/555 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1196785528, COSV100308476; called by muse, mutect2, varscan2
- FAM171A1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 245/507 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs574266280; called by muse, mutect2, varscan2
- FAM189A1 | c.728del p.P243Hfs*71 | Frame Shift Del (DEL) | VAF 350/913 reads (38%) | catalogued as COSV99720881; called by pindel, varscan2
- FAM189A1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 166/409 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768291963; called by muse, varscan2
- FAM71A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 309/611 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs777022954, COSV54235101, COSV54236851; called by muse, mutect2, varscan2
- FAM83C | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs561188076, COSV65583802; called by muse, mutect2, varscan2
- FAM90A1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 212/401 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751330423, COSV56711564; called by muse, mutect2, varscan2
- FAM98C | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 200/412 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768768718; called by muse, mutect2, varscan2
- FANCE | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 187/387 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs377415237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 351/748 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031448244; called by muse, mutect2, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 636/1022 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs140898888; called by muse, mutect2, varscan2
- FAT3 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 157/321 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as rs774983511, COSV53121160; called by muse, mutect2, varscan2
- FBF1 | c.2870G>A p.R957Q (on ENST00000586717; = p.R972Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 324/667 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs553617516; called by muse, mutect2, varscan2
- FBN1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 35/778 reads (4%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.939); catalogued as COSV57325037; called by muse, mutect2
- FBN2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 424/684 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs863223559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 242/502 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs775995098, COSV66665310, COSV66668783; called by muse, mutect2, varscan2
- FBXO24 | c.1465C>T p.R489C (on ENST00000241071 / NM_033506.3; = p.R527C on NM_012172.5) | Missense Mutation (SNP) | VAF 262/566 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs762948451, COSV53828731; called by muse, mutect2, varscan2
- FBXO41 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 345/723 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs879431027; called by muse, mutect2, varscan2
- FBXW11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 217/382 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs773518789, COSV51612643; called by muse, mutect2, varscan2
- FGD2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779897171; called by muse, mutect2, varscan2
- FGD3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 293/453 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770049768; called by muse, mutect2, varscan2
- FGD4 | c.2046C>T p.D682= | Splice Region (SNP) | VAF 193/386 reads (50%) | catalogued as rs371833051, COSV56786822; called by muse, mutect2
- FGD5 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 200/396 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs372788718; called by muse, mutect2, varscan2
- FGF8 | c.623G>A p.R208H (on ENST00000344255 / NM_033164.4; = p.R190H on NM_006119.6) | Missense Mutation (SNP) | VAF 409/820 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs769174862; called by muse, mutect2, varscan2
- FGFR4 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 616/973 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs778723081, COSV52804574, COSV52807189; called by muse, mutect2, varscan2
- FILIP1 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 158/326 reads (48%) | catalogued as rs752395530, COSV52723288, COSV52733745; called by muse, mutect2, varscan2
- FILIP1L | c.1034G>A p.R345Q (on ENST00000354552 / NM_182909.3; = p.R105Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/478 reads (49%) | SIFT tolerated (0.92); PolyPhen benign (0.13); catalogued as rs374961168; called by muse, mutect2, varscan2
- FKRP | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 274/539 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1276654268; called by muse, mutect2, varscan2
- FLG | c.6776G>A p.R2259Q | Missense Mutation (SNP) | VAF 278/610 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs542918091, COSV64246345; called by muse, mutect2
- FLG | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 204/428 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs757922040, COSV100911849; called by muse, varscan2
- FLT4 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 435/756 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99986624; called by muse, mutect2, varscan2
- FMN2 | c.2848G>A p.G950R | Missense Mutation (SNP) | VAF 187/405 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.822); catalogued as rs1276801853; called by muse, mutect2, varscan2
- FN1 | c.5741C>T p.T1914I | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs756331026; called by muse, mutect2, varscan2
- FN1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 216/449 reads (48%) | catalogued as COSV60564371; called by muse, mutect2, varscan2
- FNBP4 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 13/409 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374890464, COSV55448934; called by muse, mutect2
- FNDC11 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 282/586 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs779082342; called by muse, mutect2, varscan2
- FNDC11 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 278/526 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs752740200, COSV64442580; called by muse, varscan2
- FNDC3B | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560089040; called by muse, mutect2, varscan2
- FNDC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1356804969; called by muse, mutect2, varscan2
- FOXF1 | c.1085del p.G362Afs*17 | Frame Shift Del (DEL) | VAF 247/628 reads (39%) | catalogued as COSV52287150; called by mutect2, pindel, varscan2
- FOXI1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 291/800 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as rs371742098, COSV100089553; called by muse, mutect2, varscan2
- FOXN3 | c.1237G>A p.G413R (on ENST00000261302; = p.G391R on NM_005197.4) | Missense Mutation (SNP) | VAF 255/576 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs201853361; called by muse, mutect2, varscan2
- FRA10AC1 | c.76del p.R26Gfs*44 | Frame Shift Del (DEL) | VAF 109/271 reads (40%) | catalogued as rs755202796; called by mutect2, pindel, varscan2
- FRAS1 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 200/412 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs779986441; called by muse, varscan2
- FRAS1 | c.10268C>T p.P3423L | Missense Mutation (SNP) | VAF 211/563 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs891439423, COSV53629620; called by muse, mutect2, varscan2
- FRAT2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 380/749 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs909251895; called by muse, mutect2, varscan2
- FREM3 | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 271/541 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs776491489; called by muse, mutect2, varscan2
- FTCD | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 260/526 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144080295, COSV52423529; called by muse, varscan2
- FUT11 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 330/631 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1191668812; called by muse, varscan2
- FYCO1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 278/570 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs773743760; called by muse, mutect2, varscan2
- FZD7 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 360/691 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV53808675; called by muse, mutect2, varscan2
- FZR1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 297/620 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1293528826, COSV58053277; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 200/421 reads (48%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 420/814 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100589754; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 314/485 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GABRB2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 379/586 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs777778428, COSV50905153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 193/387 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756517614, COSV54954933; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 348/836 reads (42%) | catalogued as rs1553309006; called by mutect2, pindel, varscan2
- GAREM1 | c.2462G>A p.R821Q (on ENST00000269209 / NM_001242409.2; = p.R820Q on NM_022751.3) | Missense Mutation (SNP) | VAF 212/446 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs756156267; called by muse, mutect2, varscan2
- GARRE1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 48/1002 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100209253; called by muse, mutect2
- GAS2L2 | c.2433del p.K812Rfs*5 | Frame Shift Del (DEL) | VAF 298/750 reads (40%) | catalogued as rs782288149; called by mutect2, pindel, varscan2
- GATA4 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1245034279, COSV100633118; called by muse, mutect2, varscan2
- GATAD1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 102/233 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs564747350, COSV99843623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATAD2A | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 167/333 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.391); catalogued as rs760258128; called by muse, mutect2, varscan2
- GCN1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 172/367 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs750521946, COSV100325005; called by muse, mutect2, varscan2
- GEMIN5 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 302/466 reads (65%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs371819928; called by muse, varscan2
- GFAP | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as CM134096; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 265/564 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 106/239 reads (44%) | catalogued as rs750227570; called by mutect2, varscan2
- GLB1L2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 170/335 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746777635; called by muse, mutect2, varscan2
- GLI2 | c.2384C>T p.T795M (on ENST00000361492 / NM_001374353.1; = p.T812M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 400/825 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773308985, COSV58052651; called by muse, mutect2, varscan2
- GLIS3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs143836372; called by muse, mutect2
- GLOD4 | c.250G>A p.A84T (on ENST00000301328 / NM_001366247.1; = p.A69T on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 230/444 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs756805516; called by muse, mutect2, varscan2
- GLRB | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 96/222 reads (43%) | catalogued as COSV52420477; called by muse, mutect2, varscan2
- GNAI2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 164/380 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782805532; called by muse, mutect2, varscan2
- GNL3 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 219/430 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs372615484; called by muse, mutect2, varscan2
- GPR101 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 350/351 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs144604669, COSV53239022; called by muse, mutect2, varscan2
- GPR12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 216/437 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67344032; called by muse, mutect2, varscan2
- GPR135 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 335/669 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67749879; called by muse, mutect2, varscan2
- GPR158 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 238/483 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs557143314, COSV66271826, COSV66282257; called by muse, mutect2, varscan2
- GPR174 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 296/296 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200548821, CM136727; called by muse, mutect2, varscan2
- GPR62 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 360/711 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59055832; called by muse, mutect2, varscan2
- GPR89A | c.337dup p.S113Ffs*71 | Frame Shift Ins (INS) | VAF 72/237 reads (30%) | catalogued as rs1256102621; called by mutect2, pindel, varscan2
- GPRC5B | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 225/510 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs530209030; called by muse, mutect2, varscan2
- GPRIN2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 191/1309 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs781936680; called by muse, mutect2, varscan2
- GRHPR | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 257/519 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774233908, COSV58944706; called by muse, mutect2, varscan2
- GRID1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 218/450 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs760195348, COSV60025408; called by muse, mutect2, varscan2
- GRIN3B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 381/733 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1369396143; called by muse, mutect2, varscan2
- GRM1 | c.544del p.Q182Rfs*11 | Frame Shift Del (DEL) | VAF 220/602 reads (37%) | catalogued as rs1421731846; called by pindel, varscan2
- GRM1 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 200/393 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746660819, COSV51174083; called by muse, mutect2, varscan2
- GRM5 | c.3497C>T p.P1166L (on ENST00000305447 / NM_001143831.2; = p.P1134L on NM_000842.4) | Missense Mutation (SNP) | VAF 261/583 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs1317020135; called by muse, mutect2, varscan2
- GRXCR2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 482/707 reads (68%) | catalogued as rs762841261; called by muse, mutect2, varscan2
- GSG1L | c.898C>T p.R300* (on ENST00000447459 / NM_001109763.2; = p.R145* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 178/382 reads (47%) | catalogued as rs763637151, COSV101093691, COSV66580614; called by muse, mutect2, varscan2
- GTF2IRD2B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs782552756; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 182/461 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs202112649; called by muse, mutect2, varscan2
- GTF3C1 | c.1907+1G>A p.X636_splice | Splice Site (SNP) | VAF 140/278 reads (50%) | catalogued as COSV62240602; called by muse, mutect2, varscan2
- GTF3C4 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 191/755 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.036); catalogued as rs749149752; called by muse, mutect2, varscan2
- GUCY2C | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376847075; called by muse, mutect2, varscan2
- GYPC | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 245/492 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs149400883; called by muse, mutect2, varscan2
- H4C9 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 287/598 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100574868; called by muse, mutect2, varscan2
- HAPLN3 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 454/842 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773603379; called by muse, mutect2, varscan2
- HAPLN3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 296/624 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199664746, COSV62084501; called by muse, mutect2, varscan2
- HAS1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 410/922 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV55787516; called by muse, mutect2
- HAS3 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 277/595 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs746052927, COSV54706161; called by muse, mutect2, varscan2
- HCK | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 157/317 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757866724, COSV99393939, COSV99394128; called by muse, mutect2, varscan2
- HCN1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 191/390 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV57518436; called by muse, mutect2, varscan2
- HCN3 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 248/466 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1481497043; called by muse, mutect2, varscan2
- HCRTR2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 210/415 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV63796162; called by muse, mutect2, varscan2
- HDGFL1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 383/691 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1184843939, COSV57751246; called by muse, mutect2, varscan2
- HEATR5A | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 199/411 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs372690763; called by muse, mutect2, varscan2
- HECTD4 | c.11486C>T p.T3829M | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746255951, COSV66395002; called by muse, mutect2, varscan2
- HECTD4 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 219/437 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1208722334; called by muse, mutect2, varscan2
- HECW1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 328/655 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs532143087, COSV67829190; called by muse, mutect2, varscan2
- HEG1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 269/548 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1187475335; called by muse, mutect2, varscan2
- HELZ2 | c.6271G>A p.V2091I (on ENST00000467148 / NM_001037335.2; = p.V1522I on NM_033405.3) | Missense Mutation (SNP) | VAF 181/405 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1024311463, COSV71296137; called by muse, varscan2
- HEMGN | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 228/759 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52325922; called by muse, mutect2, varscan2
- HEPACAM | c.117del p.V40Cfs*3 | Frame Shift Del (DEL) | VAF 137/387 reads (35%) | catalogued as COSV53430012; called by mutect2, pindel, varscan2
- HERC1 | c.12728del p.K4243Rfs*12 | Frame Shift Del (DEL) | VAF 174/413 reads (42%) | catalogued as rs1487761198; called by mutect2, pindel, varscan2
- HERC1 | c.12001T>G p.L4001V | Missense Mutation (SNP) | VAF 163/319 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.397); catalogued as rs1177171990; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 156/413 reads (38%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HERC6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371365965; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 256/507 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2, varscan2
- HEYL | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 361/709 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs778733690, COSV65722022; called by muse, mutect2, varscan2
- HGF | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 174/356 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0.034); catalogued as COSV55948803; called by muse, mutect2, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 170/381 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 163/389 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIF1A | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 153/359 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1251468432, COSV60189211, COSV60191098; called by muse, mutect2, varscan2
- HIP1R | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 227/472 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1476901365; called by muse, varscan2
- HKDC1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 230/479 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs140372000; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 21/212 reads (10%) | catalogued as rs199474609; called by mutect2, varscan2
- HMCN1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 147/285 reads (52%) | catalogued as rs776450081, COSV54876415; called by muse, mutect2, varscan2
- HMCN1 | c.6250G>A p.V2084M | Missense Mutation (SNP) | VAF 137/307 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs577324065, COSV54933716; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 128/388 reads (33%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPM | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 431/845 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs770127136, COSV99725821; called by muse, mutect2, varscan2
- HOXA6 | c.63_65del p.F21del | In Frame Del (DEL) | VAF 200/426 reads (47%) | catalogued as rs776564519; called by pindel, varscan2
- HOXB3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 219/462 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1165198439; called by muse, mutect2, varscan2
- HSDL1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 165/346 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771834957, COSV99550291; called by muse, mutect2, varscan2
- HSPG2 | c.5656C>T p.R1886C | Missense Mutation (SNP) | VAF 188/403 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs566129415, COSV65969378; called by muse, mutect2, varscan2
- HSPG2 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 282/678 reads (42%) | catalogued as rs748430221; called by muse, varscan2
- HTT | c.5827G>A p.V1943I | Missense Mutation (SNP) | VAF 219/497 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201639415, COSV100750329; called by muse, mutect2, varscan2
- HYDIN | c.7081C>T p.R2361W | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755200815; called by mutect2, varscan2
- ICAM1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 41/662 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs989473316, COSV53426543; called by muse, mutect2
- IFNL3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 250/560 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs146276429, COSV69829889; called by muse, mutect2, varscan2
- IGF1R | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 300/584 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs773205989; called by muse, mutect2, varscan2
- IGHMBP2 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 195/389 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747465472, COSV99661657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 23/560 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1490407053; called by muse, mutect2
- IGKV2D-26 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 109/257 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1171015961; called by muse, mutect2, varscan2
- IGSF22 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 231/449 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs372284868; called by muse, mutect2, varscan2
- IKZF1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 243/526 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792511; called by muse, mutect2, varscan2
- IL17RA | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 191/366 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746356951; called by muse, mutect2, varscan2
- IL17RC | c.1099G>A p.A367T (on ENST00000295981 / NM_153461.4; = p.A281T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/436 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776089912, COSV55974769; called by muse, mutect2, varscan2
- IL17RE | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 199/466 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs992398278; called by muse, mutect2, varscan2
- IL25 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 282/573 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs767350854, COSV59306867; called by muse, mutect2
- IL32 | c.424G>A p.A142T (on ENST00000396890 / NM_001308078.4; = p.A96T on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs1402458039, COSV99145452; called by muse, mutect2
- IL36A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751426211, COSV52082570; called by muse, mutect2
- IL5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 141/435 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs201223432, COSV51504888; called by muse, mutect2, varscan2
- IL6ST | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 96/227 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763726030; called by muse, mutect2, varscan2
- INCENP | c.2233C>T p.R745W (on ENST00000394818 / NM_001040694.2; = p.R741W on NM_020238.3) | Missense Mutation (SNP) | VAF 204/409 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs550675425, COSV53917435; called by muse, mutect2, varscan2
- INHBA | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 260/538 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749750926; called by muse, mutect2, varscan2
- INHBC | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 254/539 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751900631; called by muse, mutect2, varscan2
- INPP4B | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 113/234 reads (48%) | catalogued as rs1330358087, COSV99526997; called by muse, mutect2, varscan2
- INSL3 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 423/840 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1000129052, COSV100427628; called by muse, mutect2
- INTS13 | c.1489dup p.T497Nfs*7 | Frame Shift Ins (INS) | VAF 114/354 reads (32%) | catalogued as rs1363242314; called by pindel, varscan2
- INTS5 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 241/501 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs778593558; called by muse, mutect2, varscan2
- INTU | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 191/361 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs758939107, COSV58871580; called by muse, mutect2, varscan2
- INVS | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 179/542 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752692382, COSV104389905; called by muse, mutect2, varscan2
- IPO13 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 174/369 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1339860243, COSV64893732; called by muse, mutect2, varscan2
- IQSEC3 | c.1462G>A p.V488I (on ENST00000538872 / NM_001170738.2; = p.V185I on NM_015232.1) | Missense Mutation (SNP) | VAF 322/676 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV58284848; called by muse, mutect2, varscan2
- IRAG1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 166/360 reads (46%) | catalogued as rs774988512, COSV101350891, COSV70212604; called by muse, mutect2, varscan2
- IRGQ | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 344/695 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV60670227; called by muse, mutect2, varscan2
- IRS1 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 314/625 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756434990, COSV59340025; called by muse, varscan2
- IRS2 | c.2100_2105del p.A701_V702del | In Frame Del (DEL) | VAF 326/896 reads (36%) | catalogued as rs1566413592; called by pindel, varscan2
- IRX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100121697; called by muse, mutect2, varscan2
- ISLR2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 331/700 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1395632632, COSV100679355; called by muse, mutect2, varscan2
- ITGAD | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 155/334 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs369360258; called by muse, mutect2, varscan2
- ITGAD | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 147/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201870715; called by muse, mutect2, varscan2
- ITIH3 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 201/388 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs762645645, COSV99820054; called by muse, mutect2, varscan2
- ITPR2 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781558920; called by muse, varscan2
- ITPR2 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 156/376 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs535598972, COSV67277748; called by muse, mutect2, varscan2
- ITPR3 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs778240357, COSV65415980; called by muse, mutect2, varscan2
- ITSN1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 251/546 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779207769; called by muse, mutect2, varscan2
- IWS1 | c.1745del p.K582Sfs*4 | Frame Shift Del (DEL) | VAF 142/400 reads (36%) | catalogued as rs1558747232; called by mutect2, pindel, varscan2
- JPT1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1396407786, COSV59173228; called by muse, mutect2, varscan2
- KAT2A | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782071302; called by muse, mutect2, varscan2
- KAT6B | c.6154G>A p.G2052R | Missense Mutation (SNP) | VAF 264/552 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs756847080; called by muse, mutect2, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 181/357 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 222/470 reads (47%) | catalogued as rs1258313537; called by mutect2, varscan2
- KCNA6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 251/507 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.057); catalogued as rs778896791; called by muse, mutect2, varscan2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 220/540 reads (41%) | catalogued as COSV73053085; called by mutect2, pindel, varscan2
- KCNC1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 305/605 reads (50%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1305576844, COSV56394680; called by muse, mutect2, varscan2
- KCND3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 335/721 reads (46%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.039); catalogued as rs774713377, COSV56175352; called by muse, mutect2, varscan2
- KCND3 | c.948C>A p.S316R | Missense Mutation (SNP) | VAF 238/472 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as COSV56182496; called by muse, mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 245/496 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2, varscan2
- KCNG3 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 268/507 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370971617, COSV100045291; called by muse, mutect2, varscan2
- KCNJ14 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 373/769 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1156545913, COSV60738453, COSV60738556; called by muse, mutect2, varscan2
- KCNQ5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 119/233 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs1562230186, COSV59658525; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 171/385 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KCNT1 | c.1660C>T p.R554C (on ENST00000488444; = p.R573C on NM_020822.3) | Missense Mutation (SNP) | VAF 488/798 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs557219607, COSV53706654; ClinVar: uncertain significance; called by muse, mutect2
- KCNV1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 208/427 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1157202808, COSV52084721; called by muse, mutect2, varscan2
- KCNV2 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs766187569, COSV101172463, COSV66056982; called by muse, mutect2
- KCTD12 | c.125del p.G42Afs*5 | Frame Shift Del (DEL) | VAF 310/734 reads (42%) | catalogued as COSV58524529; called by mutect2, pindel, varscan2
- KDM4C | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 105/117 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs776351428, COSV67187037; called by muse, mutect2, varscan2
- KHDRBS3 | c.948C>T p.Y316= | Splice Region (SNP) | VAF 210/453 reads (46%) | catalogued as rs373585149; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 243/594 reads (41%) | catalogued as COSV56813511; called by mutect2, pindel, varscan2
- KIAA1522 | c.2705G>A p.R902Q (on ENST00000373480 / NM_001198972.2; = p.R961Q on NM_020888.3) | Missense Mutation (SNP) | VAF 263/559 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs374716724; called by muse, varscan2
- KIF18B | c.1471G>A p.V491M (on ENST00000593135 / NM_001265577.2; = p.V503M on NM_001264573.2) | Missense Mutation (SNP) | VAF 210/408 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs769795016, COSV59274303; called by muse, varscan2
- KIFC1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 490/951 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs201396332, COSV65729182; called by muse, mutect2, varscan2
- KIRREL1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 161/342 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474957010; called by muse, mutect2, varscan2
- KIRREL2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 242/516 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767203597, COSV52875861; called by muse, varscan2
- KISS1R | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 400/807 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757918057; called by muse, mutect2, varscan2
- KLC2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 206/402 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs771453461; called by muse, mutect2, varscan2
- KLF7 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 262/546 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747043061; called by muse, mutect2, varscan2
- KLHL41 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 190/416 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99500286; called by muse, mutect2, varscan2
- KMT2B | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 352/733 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55863591; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 366/948 reads (39%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KMT2D | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 304/645 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.47); catalogued as rs777682865, COSV56473406; called by muse, mutect2, varscan2
- KPNA3 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 99/282 reads (35%) | catalogued as COSV55507483; called by muse, mutect2, varscan2
- KRT13 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 266/576 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs145116138; called by muse, mutect2, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 299/684 reads (44%) | catalogued as rs769596857; called by mutect2, pindel, varscan2
- KRT222 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 265/528 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs751191563, COSV67498703; called by muse, varscan2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 406/887 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT72 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 224/496 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368767777, COSV53374553; called by muse, mutect2
- KRT79 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 274/594 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1368877804; called by muse, mutect2, varscan2
- KRT80 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 340/662 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs764141245, COSV100502545; called by muse, mutect2, varscan2
- KSR1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 163/324 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs776835480, COSV99259102; called by muse, mutect2, varscan2
- L1CAM | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 288/289 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs782070899, COSV62828384; called by muse, mutect2, varscan2
- L3MBTL3 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 228/451 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs769544082, COSV62390054; called by muse, mutect2, varscan2
- LACTBL1 | c.611C>T p.S204L (on ENST00000618559; = p.S249L on NM_001289974.2) | Missense Mutation (SNP) | VAF 316/618 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1318546041; called by muse, mutect2, varscan2
- LAMA5 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749953963; called by muse, mutect2, varscan2
- LARGE1 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 296/609 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146923365; called by muse, varscan2
- LARGE1 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 193/404 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as rs1556032013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LARP1 | c.2702G>A p.R901Q (on ENST00000518297 / NM_033551.3; = p.R824Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 199/561 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450704, COSV60427870; called by muse, mutect2, varscan2
- LARP4B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866154645, COSV60223537; called by muse, mutect2, varscan2
- LCE2A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 293/609 reads (48%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs753692865, COSV64226821; called by muse, mutect2, varscan2
- LDHA | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs199859192, COSV57041331; called by muse, mutect2, varscan2
- LDLR | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs770696696, CM091471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEFTY1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 330/734 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1410615103; called by muse, mutect2, varscan2
- LHFPL5 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 238/517 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs376479168; called by muse, mutect2, varscan2
- LIFR | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 216/426 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.315); catalogued as COSV54691142; called by muse, mutect2, varscan2
- LILRA1 | c.72G>A p.G24= | Splice Region (SNP) | VAF 109/319 reads (34%) | catalogued as rs765286954, COSV99251940; called by muse, mutect2, varscan2
- LILRA4 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 298/651 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs750275949, COSV99392780; called by muse, mutect2, varscan2
- LILRB4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 317/660 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs145519196, COSV54409351; called by muse, mutect2, varscan2
- LIMCH1 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 60/549 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs547344878, COSV58272497; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 284/622 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs369219844; called by muse, mutect2, varscan2
- LINGO4 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 273/603 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs748289467; called by muse, mutect2, varscan2
- LIPG | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 213/434 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs536799767, COSV54296081; called by muse, mutect2, varscan2
- LKAAEAR1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 414/824 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as rs1055207954; called by muse, mutect2, varscan2
- LMAN1L | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 274/625 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs202021967; called by muse, mutect2, varscan2
- LMAN2L | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 158/357 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748501432; called by muse, mutect2, varscan2
- LMLN2 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 186/394 reads (47%) | catalogued as rs987609587; called by muse, mutect2, varscan2
- LMX1B | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.616); catalogued as rs765969991; called by muse, mutect2, varscan2
- LONP1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 223/409 reads (55%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as rs149596661; called by muse, mutect2, varscan2
- LOXHD1 | c.5474G>A p.R1825Q (on ENST00000642948; = p.R1763Q on NM_144612.7) | Missense Mutation (SNP) | VAF 199/454 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs771185362; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 89/174 reads (51%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRP1 | c.11062G>A p.E3688K | Missense Mutation (SNP) | VAF 173/361 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs201541007; called by muse, mutect2, varscan2
- LRP1B | c.10454del p.N3485Tfs*33 | Frame Shift Del (DEL) | VAF 155/391 reads (40%) | catalogued as rs79925984; called by mutect2, pindel, varscan2
- LRP2 | c.13832C>T p.A4611V | Missense Mutation (SNP) | VAF 164/357 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs529198764, COSV55540455; called by muse, mutect2, varscan2
- LRP2 | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs748382645, COSV55565358; called by muse, varscan2
- LRP4 | c.5498G>A p.R1833Q | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as rs771256759, COSV66135635; called by muse, varscan2
- LRP4 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs775191643; called by muse, mutect2, varscan2
- LRRC14 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 246/585 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs1337625543, COSV52879975; called by muse, mutect2, varscan2
- LRRC27 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 217/452 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs112727561; called by muse, varscan2
- LRRC37A3 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 159/668 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1193621508; called by muse, varscan2
- LRRC43 | c.1820_1822del p.K607del | In Frame Del (DEL) | VAF 176/357 reads (49%) | catalogued as rs770573768; called by pindel, varscan2
- LRRC49 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.805); catalogued as rs767471553; called by muse, mutect2, varscan2
- LRRC4B | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 413/869 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1276337308, COSV100976105; called by muse, mutect2, varscan2
- LRRC4C | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 220/455 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.54); catalogued as rs201412968, COSV53425400, COSV53430470; called by muse, varscan2
- LRRC7 | c.1480C>T p.R494C (on ENST00000651989 / NM_001370785.2; = p.R461C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/284 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765562100; called by muse, mutect2, varscan2
- LRWD1 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 219/421 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs150396748; called by muse, mutect2, varscan2
- LSM10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 250/531 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as rs943465242; called by muse, varscan2
- LSM11 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 190/645 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs769770410, COSV53848901; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 149/340 reads (44%) | catalogued as rs753028254; called by mutect2, pindel, varscan2
- LZTS1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 290/613 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.518); catalogued as rs1259821365; called by muse, mutect2, varscan2
- MAG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 272/570 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs372192843; called by muse, mutect2, varscan2
- MAGEB6B | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1346788256, COSV69689992; called by muse, mutect2, varscan2
- MAGI2 | c.4112C>T p.A1371V | Missense Mutation (SNP) | VAF 165/289 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs13438363; called by muse, mutect2, varscan2
- MALRD1 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 198/423 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs1282298965; called by muse, mutect2, varscan2
- MALSU1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 156/323 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747613839, COSV54978160; called by muse, mutect2, varscan2
- MAMDC4 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 302/653 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1383747941, COSV56031702; called by muse, mutect2, varscan2
- MAN1B1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 248/541 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1488519885; called by muse, mutect2, varscan2
- MAN2A2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 248/523 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144478704; called by muse, mutect2, varscan2
- MAN2A2 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 319/694 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146996561; called by muse, mutect2, varscan2
- MAN2B2 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 156/322 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs569059179; called by muse, mutect2, varscan2
- MAN2C1 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 199/414 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as rs778458430, COSV51237082; called by muse, mutect2, varscan2
- MAP1A | c.2021C>T p.A674V | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs369443962; called by muse, mutect2, varscan2
- MAP1S | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 390/822 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773801022; called by muse, mutect2
- MAP2K5 | c.1306C>T p.R436W (on ENST00000178640 / NM_145160.3; = p.R426W on NM_002757.4) | Missense Mutation (SNP) | VAF 281/579 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs762647820; called by muse, mutect2, varscan2
- MAP3K9 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs961518449; called by muse, mutect2, varscan2
- MAP7D1 | c.245dup p.Q83Afs*8 | Frame Shift Ins (INS) | VAF 176/456 reads (39%) | catalogued as rs765962881; called by mutect2, varscan2
- MAPK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 196/491 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as rs748679283; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 174/366 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs763939482, COSV51726366; called by muse, varscan2
- MARCHF1 | c.680G>A p.R227H (on ENST00000274056; = p.R210H on NM_017923.4) | Missense Mutation (SNP) | VAF 234/489 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs779641825; called by muse, mutect2, varscan2
- MARF1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 336/703 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs201651611; called by muse, mutect2, varscan2
- MATN2 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 208/422 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774927507, COSV54714909; called by muse, varscan2
- MATN2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 194/411 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs200270504; called by muse, varscan2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 193/384 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 348/746 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- MCCC2 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV60157586; called by muse, mutect2, varscan2
- MCM2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 149/266 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273687863; called by muse, varscan2
- MCM2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768322698; called by muse, mutect2, varscan2
- MCM3 | c.454G>A p.V152I (on ENST00000229854 / NM_001366374.2; = p.V142I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 168/329 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs1033238760, COSV57719478; called by muse, mutect2, varscan2
- MDC1 | c.5869C>T p.R1957C | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770859881; called by muse, varscan2
- MDH1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV51862786; called by mutect2, varscan2
- MDN1 | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65520068; called by muse, mutect2, varscan2
- MED1 | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 178/351 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771798336; called by muse, mutect2, varscan2
- MEF2B | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 200/398 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs750716565; called by muse, mutect2, varscan2
- MEF2D | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 302/663 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752408015, COSV61730368; called by muse, mutect2, varscan2
- MEGF10 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 193/581 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs754183529; called by muse, mutect2, varscan2
- MEGF6 | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 279/651 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1202873987; called by muse, mutect2, varscan2
- MEIOB | c.1del p.M1? | Frame Shift Del (DEL) | VAF 103/271 reads (38%) | catalogued as rs756894401; called by mutect2, pindel, varscan2
- MEIS2 | c.562G>A p.V188I (on ENST00000561208 / NM_170675.5; = p.V175I on NM_002399.3) | Missense Mutation (SNP) | VAF 223/480 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs762490597; called by muse, mutect2, varscan2
- METTL21A | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 198/396 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374826319; called by muse, mutect2, varscan2
- METTL7B | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 271/548 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57692121; called by muse, mutect2, varscan2
- MFGE8 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 200/424 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs568619975; called by muse, mutect2, varscan2
- MFHAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 291/548 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52284172; called by muse, mutect2, varscan2
- MFSD2B | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 241/548 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs756008102; called by muse, mutect2, varscan2
- MGAT4B | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 246/724 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748605549, COSV99482332; called by muse, mutect2, varscan2
- MGLL | c.491C>T p.A164V (on ENST00000398104 / NM_001003794.2; = p.A174V on NM_007283.6) | Missense Mutation (SNP) | VAF 198/359 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs374353919; called by muse, mutect2, varscan2
- MGLL | c.392C>T p.T131M (on ENST00000398104 / NM_001003794.2; = p.T141M on NM_007283.6) | Missense Mutation (SNP) | VAF 210/428 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs773416847; called by muse, varscan2
- MINAR1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 247/510 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775338460, COSV59582058; called by muse, mutect2, varscan2
- MLIP | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs145131028; called by muse, mutect2, varscan2
- MLLT10 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 128/294 reads (44%) | catalogued as rs1179221232, COSV57004712; called by muse, varscan2
- MMEL1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 286/589 reads (49%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs372890618; called by muse, mutect2, varscan2
- MMP7 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 172/338 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs542899524, COSV52772100; called by muse, varscan2
- MON2 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 90/203 reads (44%) | catalogued as rs1379822048, COSV54803143; called by muse, mutect2, varscan2
- MORC2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 147/334 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1034098965; called by muse, mutect2, varscan2
- MPEG1 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 201/411 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs369599067; called by muse, mutect2, varscan2
- MPRIP | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 296/583 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1175028801; called by muse, mutect2, varscan2
- MRC2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 227/473 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.823); catalogued as rs368122647; called by muse, mutect2, varscan2
- MRGPRX1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 214/704 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs760583024, COSV57109647; called by muse, mutect2, varscan2
- MRM3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 262/502 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs761278369, COSV58680856; called by muse, mutect2, varscan2
- MROH2A | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1201608726; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 289/588 reads (49%) | catalogued as rs1558718327, COSV62567684; called by mutect2, varscan2
- MRPL21 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 140/332 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201987235, COSV62913775; called by muse, mutect2, varscan2
- MRPS18B | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 243/552 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1197838687; called by muse, mutect2, varscan2
- MSANTD4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 202/438 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1177741904; called by muse, mutect2, varscan2
- MSL3 | c.980C>T p.P327L (on ENST00000312196 / NM_078629.4; = p.P161L on NM_006800.4) | Missense Mutation (SNP) | VAF 59/355 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs374392862; called by muse, mutect2, varscan2
- MST1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 312/638 reads (49%) | catalogued as rs1216259052, COSV56565834; called by muse, mutect2, varscan2
- MTHFR | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200056619, CM127686; called by muse, mutect2, varscan2
- MTMR12 | c.2065del p.Q689Rfs*8 | Frame Shift Del (DEL) | VAF 240/470 reads (51%) | catalogued as rs1166239304; called by mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 102/279 reads (37%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MTSS2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 333/720 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs374985478; called by muse, varscan2
2,102 further variants in this file (1,322 protein-altering or splice-affecting, 691 silent, 89 other) are not listed here.
